Somatic mutation profile of tumor specimen TCGA-HU-A4G3-01A (aliquot TCGA-HU-A4G3-01A-11D-A24D-08) from TCGA case TCGA-HU-A4G3, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 54.9 years (20,064 days).
Specimen TCGA-HU-A4G3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fdfaed4-8f1f-4d47-9969-7025bd3ca37b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-A4G3-10A (Blood Derived Normal), aliquot TCGA-HU-A4G3-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d215d4d-6830-47ad-b513-e13e65c7657d

The open-access MAF lists 113 somatic variants for this specimen: 84 protein-altering or splice-affecting, 27 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 27, Frame Shift Ins 3, Frame Shift Del 3, In Frame Del 2, Nonsense Mutation 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.6472C>T p.R2158* | Nonsense Mutation (SNP) | VAF 9/103 reads (9%) | hotspot (GDC flag); catalogued as COSV61370611, COSV61381711; called by muse, mutect2
- AASS | c.1103A>C p.E368A | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV62791815; called by muse, mutect2
- ABCC3 | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.041); catalogued as COSV53319042; called by muse, mutect2, varscan2
- ADAMTS12 | c.2101T>C p.C701R | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61279838; called by muse, mutect2, varscan2
- ADAMTS19 | c.908T>G p.I303S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.197); catalogued as COSV50795652, COSV50798314; called by muse, mutect2, varscan2
- AP1B1 | c.2506G>A p.V836M | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs747171072, COSV58023472; called by muse, mutect2, varscan2
- ARHGEF2 | c.920C>A p.P307H (on ENST00000361247 / NM_001162383.2; = p.P279H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as COSV58117211; called by muse, mutect2, varscan2
- ATP6V1C2 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1474755358, COSV55359546; called by muse, varscan2
- BASP1 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs1438741253, COSV59473591; called by muse, mutect2, varscan2
- C11orf16 | c.178T>C p.S60P | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.187); catalogued as COSV58169096; called by muse, mutect2
- CACNA1E | c.5089G>T p.D1697Y | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as COSV62387967, COSV62424409; called by muse, mutect2, varscan2
- CAMK2B | c.1816C>T p.H606Y | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51666573; called by muse, mutect2, varscan2
- CCDC71 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs753666480, COSV58910751; called by muse, mutect2, varscan2
- CD1B | c.686T>A p.F229Y | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63805202; called by muse, mutect2, varscan2
- CDH2 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52296330; called by muse, mutect2, varscan2
- CHRNB1 | c.982G>A p.V328M | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as rs865958957, COSV60142262; called by muse, mutect2
- CNTN3 | c.1966A>G p.K656E | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.216); catalogued as COSV55184365; called by muse, mutect2, varscan2
- COL6A2 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.97); PolyPhen benign (0.1); catalogued as rs768434256, COSV55998741, COSV56014057; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPNE9 | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56069192; called by muse, mutect2, varscan2
- CSMD1 | c.5413G>A p.G1805S (on ENST00000520002; = p.G1804S on NM_033225.6) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs375979816, COSV99045806; called by muse, mutect2, varscan2
- DDI1 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs770274476, COSV56381028; called by muse, mutect2
- DIAPH3 | c.2914G>A p.E972K (on ENST00000400324 / NM_001042517.2; = p.E709K on NM_030932.3) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs781747042, COSV57367897; called by muse, mutect2, varscan2
- DPEP3 | c.552C>A p.N184K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV52052858; called by muse, mutect2, varscan2
- DPP10 | c.268A>G p.N90D | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs1468612489, COSV59728280; called by muse, mutect2
- EDNRB | c.1147del p.Y383Ifs*3 (on ENST00000377211 / NM_001201397.1; = p.Y293Ifs*3 on NM_000115.5) | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | catalogued as rs769735757; ClinVar: risk factor; called by mutect2, pindel, varscan2
- EPB41L3 | c.1610G>T p.C537F | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100550355; called by muse, mutect2, varscan2
- EYS | c.376T>G p.F126V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as COSV61000180; called by muse, mutect2, varscan2
- FAN1 | c.2435G>A p.C812Y | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62952147; called by muse, mutect2, varscan2
- FPR2 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.065); catalogued as rs199862216, COSV60673384; called by muse, mutect2, varscan2
- GALNT9 | c.1504C>T p.R502W (on ENST00000328957 / NM_001122636.2; = p.R136W on NM_021808.3) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs763735503, COSV61103339; called by mutect2, varscan2
- GJA1 | c.204G>C p.K68N | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as COSV99247339; called by muse, mutect2, varscan2
- GRIN2B | c.2639G>A p.R880H | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.871); catalogued as rs904771425, COSV74205198, COSV74206925; called by muse, mutect2, varscan2
- GRK1 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.175); catalogued as rs745390037, COSV59552966; called by muse, mutect2, varscan2
- HDAC3 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as rs748543297, COSV59497879; called by muse, mutect2, varscan2
- HMCN1 | c.11377C>T p.R3793C | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147547755, COSV54892188; called by muse, mutect2, varscan2
- IPO7 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs376273953; called by muse, mutect2, varscan2
- KPNB1 | c.2419G>A p.D807N | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.905); catalogued as COSV51600604; called by muse, mutect2, varscan2
- LCMT2 | c.1505G>T p.S502I | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV59791778; called by muse, mutect2, varscan2
- LMBRD2 | c.1024A>G p.K342E | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV56952825; called by muse, mutect2
- LPCAT2 | c.1523C>T p.T508M | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.247); catalogued as rs772603938, COSV50894391; called by muse, mutect2, varscan2
- LRBA | c.7967A>T p.Y2656F | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs775871299, COSV63964930; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRK1 | c.3262G>A p.E1088K | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752554538, COSV52618146; called by muse, mutect2, varscan2
- MAGEC1 | c.187T>C p.S63P | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.403); catalogued as COSV53581658; called by muse, mutect2
- MCM6 | c.1273A>G p.S425G | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV51469389; called by muse, mutect2, varscan2
- MPL | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.249); catalogued as rs1215318596, COSV65244230; called by muse, mutect2, varscan2
- MROH2B | c.3305C>T p.T1102I | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV68189532; called by muse, mutect2
- MTMR11 | c.812G>T p.R271L (on ENST00000439741 / NM_001145862.2; = p.R199L on NM_181873.3) | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63808714; called by muse, mutect2, varscan2
- MYH14 | c.1799C>T p.A600V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764094116, COSV51831320; called by muse, mutect2, varscan2
- NHLRC2 | c.2081G>T p.S694I | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.244); catalogued as COSV65176052; called by muse, mutect2, varscan2
- NPHP4 | c.4261G>A p.V1421M | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371657189, COSV100976968; called by muse, mutect2, varscan2
- OR2M5 | c.418A>C p.I140L | Missense Mutation (SNP) | VAF 40/356 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0.014); catalogued as COSV63545771, COSV63547046; called by muse, varscan2
- P2RY6 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.761); catalogued as rs141420011; called by muse, mutect2, varscan2
- PC | c.2545G>A p.D849N | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs1200819608, COSV58994140; called by muse, mutect2
- PCDHGB6 | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.097); catalogued as COSV53984266, COSV54055529; called by muse, mutect2
- PLEKHA2 | c.643T>A p.W215R | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66243518; called by muse, mutect2
- PPP2R2B | c.863A>C p.K288T (on ENST00000394409; = p.K354T on NM_181674.2) | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV100355234, COSV60779665; called by muse, mutect2, varscan2
- PYGO2 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV63757230; called by muse, mutect2
- RABGEF1 | c.1427C>A p.P476Q (on ENST00000439720 / NM_001287061.2; = p.P463Q on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.061); catalogued as COSV53165192, COSV53165242; called by muse, mutect2
- SAGE1 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV61017955; called by muse, mutect2
- SALL1 | c.3836C>T p.T1279M | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs776104367, COSV51754116, COSV51762582; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA6D | c.1206_1207insT p.V403Cfs*7 | Frame Shift Ins (INS) | VAF 11/61 reads (18%) | catalogued as COSV100317678; called by mutect2, pindel, varscan2
- SERPINB3 | c.1136A>C p.N379T | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV52189592; called by muse, mutect2, varscan2
- SLC12A7 | c.2719G>A p.E907K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as rs765374153, COSV53754510; called by muse, mutect2, varscan2
- SORCS3 | c.3274T>G p.L1092V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.49); catalogued as COSV63820477; called by muse, mutect2, varscan2
- TCF12 | c.1266del p.T423Pfs*72 | Frame Shift Del (DEL) | VAF 9/98 reads (9%) | catalogued as COSV51010449; called by mutect2, pindel
- TEKT1 | c.889A>T p.T297S | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100106452; called by muse, varscan2
- THSD7B | c.4196G>T p.R1399L (on ENST00000272643; = p.R1397L on NM_001316349.2) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.692); catalogued as COSV55686958, COSV55737827; called by muse, mutect2, varscan2
- TRIML2 | c.1156G>C p.V386L | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as COSV58718455, COSV58719554; called by muse, mutect2, varscan2
- UHRF1BP1 | c.2575A>G p.M859V | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51960528; called by muse, mutect2
- UNC5D | c.1705G>A p.G569S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs765684409, COSV54823017, COSV99779199; called by muse, mutect2, varscan2
- WBP4 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.451); catalogued as COSV65274668; called by muse, mutect2, varscan2
- WDR70 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs569699002; called by muse, mutect2, varscan2
- ZBTB38 | c.1256G>C p.G419A | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV58544210; called by muse, mutect2, varscan2
- ZFAND5 | c.125A>C p.Q42P | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV99428619; called by muse, mutect2, varscan2
- ZFAND5 | c.124C>A p.Q42K | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV99428623; called by muse, mutect2, varscan2
- ZGRF1 | c.2564G>A p.G855E | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs896620823, COSV100005802; called by muse, mutect2
- ZNHIT1 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.578); catalogued as rs1435416165, COSV56185864; called by muse, mutect2, varscan2
- ZSCAN5B | c.1142G>T p.R381I | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62001186; called by muse, mutect2, varscan2
- CD101 | c.2250dup p.F751Ifs*4 | Frame Shift Ins (INS) | VAF 7/66 reads (11%) | called by mutect2, pindel, varscan2
- CNTN1 | c.2138T>G p.V713G | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CPA3 | c.485dup p.N163Efs*2 | Frame Shift Ins (INS) | VAF 8/56 reads (14%) | called by mutect2, pindel, varscan2
- DDIAS | c.477_485del p.L160_A162del | In Frame Del (DEL) | VAF 15/141 reads (11%) | called by mutect2, pindel, varscan2
- MRPS28 | c.67_69del p.F23del | In Frame Del (DEL) | VAF 6/34 reads (18%) | called by pindel, varscan2
- OTOF | c.1969_1978del p.K657Gfs*6 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | called by mutect2, pindel, varscan2
- ANKRD11 | c.3780G>A p.S1260= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs139288405; called by muse, mutect2, varscan2
- B2M | c.141G>A p.V47= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as rs1025782955, COSV62566220; called by muse, mutect2, varscan2
- BARHL1 | c.60C>T p.P20= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs1386611779, COSV55038932; called by muse, mutect2, varscan2
- CHST5 | c.963C>T p.L321= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as rs79685933; called by muse, mutect2, varscan2
- CNTN3 | c.1428T>C p.T476= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV55165301, COSV55184374; called by muse, mutect2
- CPAMD8 | c.1137G>T p.A379= (on ENST00000651564; = p.A332= on NM_015692.5) | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99359839; called by muse, mutect2
- CSMD2 | c.828C>T p.P276= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs150632282; called by muse, mutect2
- EIF2B4 | c.1200G>A p.K400= (on ENST00000347454 / NM_001034116.2; = p.K399= on NM_015636.3) | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV61457986; called by muse, mutect2, varscan2
- EPHA8 | c.2295C>T p.N765= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1360785330, COSV51299329; called by muse, mutect2, varscan2
- FAT3 | c.12474C>T p.I4158= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs1478000445, COSV53144510; called by muse, mutect2, varscan2
- FITM1 | c.348G>A p.R116= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV52825898; called by muse, mutect2, varscan2
- HDAC4 | c.2571C>T p.V857= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV61876272; called by muse, mutect2, varscan2
- IGKV1D-8 | c.192A>G p.K64= | Silent (SNP) | VAF 31/147 reads (21%) | called by muse, mutect2, varscan2
- LILRB4 | c.1153C>T p.L385= (on ENST00000391733 / NM_001278428.3; = p.L384= on NM_001278426.3) | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV99554130; called by muse, mutect2, varscan2
- LRRC36 | c.918A>G p.S306= | Silent (SNP) | VAF 24/121 reads (20%) | catalogued as rs1045782901, COSV52082345; called by muse, mutect2, varscan2
- MLXIP | c.1176T>G p.A392= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV59837931; called by muse, mutect2
- MROH2B | c.324C>T p.F108= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs371986783; called by muse, mutect2
- NAP1L3 | c.939C>T p.D313= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV59077685; called by muse, mutect2, varscan2
- PCDHB13 | c.1422C>T p.S474= | Silent (SNP) | VAF 32/190 reads (17%) | catalogued as COSV53399622; called by muse, mutect2, varscan2
- PGLYRP2 | c.1269G>A p.T423= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV52991832; called by muse, mutect2, varscan2
- PNKP | c.663C>T p.S221= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs1376565938, COSV55590655; ClinVar: likely benign; called by muse, mutect2, varscan2
- TAF1C | c.297C>T p.V99= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs1018266084, COSV58989345; called by muse, mutect2, varscan2
- TEKT1 | c.888T>A p.I296= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as COSV100106453; called by muse, varscan2
- TET1 | c.5208C>T p.V1736= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV65389564; called by muse, mutect2, varscan2
- VAT1L | c.1122C>T p.G374= | Silent (SNP) | VAF 24/296 reads (8%) | catalogued as rs1204710218, COSV56828766; called by muse, mutect2
- VPS37B | c.61C>T p.L21= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV57361901; called by muse, mutect2
- ZNF536 | c.2844A>G p.K948= | Silent (SNP) | VAF 30/207 reads (14%) | catalogued as COSV100834607, COSV62834050; called by muse, mutect2, varscan2
- KANK3 | chr19:8322856 del TC | 3'Flank (DEL) | VAF 4/29 reads (14%) | called by pindel, varscan2
- RIMS2 | c.4064-21230C>T | Intron (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99200338; called by muse, mutect2, varscan2
